TCGA case TCGA-14-1451 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Emory University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/06c427a1-8c2d-4003-b744-139114a04440

Demographics
Sex at birth: male; Race: white; Age at index: 39 years; Vital status: Dead; Days to death: 703 days (1.9 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 39.4 years (14,401 days); Year of diagnosis: 2005; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Treatment intent type: Adjuvant; Days to treatment start: 0 days.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Initial disease status: Progressive Disease; Days to treatment start: 19 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Initial disease status: Progressive Disease; Days to treatment start: 20 days; Days to treatment end: 34 days; Number of cycles: 2; Treatment dose: 641 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 59 days; Days to treatment end: 101 days; Number of cycles: 1; Treatment dose: 5,880 mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 60 days; Days to treatment end: 101 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Initial disease status: Progressive Disease; Days to treatment start: 153 days; Treatment dose: 8 Wafer.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib; Initial disease status: Progressive Disease; Days to treatment start: 382 days (1.0 years); Days to treatment end: 504 days (1.4 years); Treatment dose: 9,000 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 411 days (1.1 years); Days to treatment end: 480 days (1.3 years); Number of cycles: 4; Treatment dose: 780 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vincristine; Initial disease status: Progressive Disease; Days to treatment start: 411 days (1.1 years); Days to treatment end: 480 days (1.3 years); Number of cycles: 4; Treatment dose: 8 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine; Initial disease status: Progressive Disease; Days to treatment start: 501 days (1.4 years); Days to treatment end: 566 days (1.5 years); Number of cycles: 2; Treatment dose: 720 mg; Route of administration: Intravenous.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 39.5 years (14,420 days); Days to diagnosis: 19 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 153 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (4 entries)
- Day 19 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 19 days.
- Days to follow up: 703 days (1.9 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-14-1451-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.7; Shortest dimension: 0.3.
  Slide TCGA-14-1451-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 0.
  Slide TCGA-14-1451-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0.
- Sample TCGA-14-1451-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-14-1451-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Gliadel; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: Other (specify below).
- Drug treatment 4: Pharmaceutical therapy drug name: Temodar; Therapy regimen: Progression.
- Drug treatment 4, Route of administrations: Route of administration: PO.
- Drug treatment 6: Pharmaceutical therapy drug name: Bcnu; Therapy regimen: Progression.
- Drug treatment 9: Pharmaceutical therapy drug name: Vincristin; Therapy regimen: Progression.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Subject positive for neoadjuvant therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 703 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 703 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 19 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-14-1451-01A-01D-0517-01): tumor purity 0.78, ploidy 1.95, whole-genome doublings 0.
